Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A2HX, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A2HX-01A (Primary Tumor).

[page 1 of 6]
CLINICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB:

Gender:

F

Ref. Physician:

Patient Address:

Location:

Service:

Urology

Billing

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Type:

INPATIENT

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

History of muscle invasive HGTC with micropapillary, signet ring, mucinous features.

Specimens Submitted:

- 1: Small intestine, "implants"; biopsy
- 2: Lymph nodes, right common iliac; excision
- 3: Lymph nodes, right pelvic; excision
- 4: Lymph nodes, presacral; excision
- 5: Lymph node, Marcille's; excision
- 6: Lymph nodes, left pelvic; excision
- 7: Lymph nodes, left common iliac; excision
- 8: Bladder, urethra and anterior vaginal wall; radical cystectomy
- 9: Stent, left ureter; removal

ICD-0-3

carcinoma, urothelial, NOS

8/20/3

Site: bladder, wall, NOS C67.9

hw 6/23/11

DIAGNOSIS:

1. Small intestine, "implants"; biopsy:
-Gastrointestinal stromal tumor, 0.9 cm.
-Immunohistochemical stains show that the tumor is diffusely positive for CD117, and negative for S100, desmin and HHF35.
2. Lymph nodes, right common iliac; excision:
Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 1
3. Lymph nodes, right pelvic; excision:
Lymph Node Dissection:
Metastatic urothelial carcinoma
Number of lymph nodes examined: 17
Number of lymph nodes with metastatic disease: 2
Size of the largest lymph node involved by tumor: 1.2cm.
Size of the largest metastatic focus: 0.2 cm.
Extranodal extension is not identified
4. Lymph nodes, presacral; excision:
Lymph Node Dissection:
Metastatic urothelial carcinoma
Number of lymph nodes examined: 6
Number of lymph nodes with metastatic disease: 1
Size of the largest lymph node involved by tumor: 0.15cm.
Size of the largest metastatic focus: 0.005 cm.

5. Lymph node, Marcille's; excision:

[page 2 of 6]
SURGICAL PATHOLOGY REPORT

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 1

6. Lymph nodes, left pelvic; excision:

Lymph Node Dissection:

Metastatic urothelial carcinoma

Number of lymph nodes examined: 10

Number of lymph nodes with metastatic disease: 1

Size of the largest lymph node involved by tumor: 1.3cm.

Size of the largest metastatic focus : 0.18 cm.

Extranodal extension is not identified

7. Lymph nodes, left common iliac; excision:

Lymph Node Dissection:

Benign fibroadipose tissue

8. Bladder, urethra and anterior vaginal wall; radical cystectomy:

Tumor Type:

Urothelial carcinoma with mixed histologic features, including: micropapillary, diffuse and signet ring cell
some treatment related changes are present

Histologic Grade:

High grade

Pattern of growth of the Non-Invasive component:

In situ component not identified

Pattern of growth of the Invasive component:

Diffuse

Tumor Multicentricity:

Not identified

the bladder wall is diffusely involved by tumor

Bladder Local Invasion:

Perivesical soft tissues

Extravesical Tumor Extension:

Ureters uninvolved

Urethra uninvolved

Tumor involves soft tissue around both ureters

Vascular Invasion:

Identified

Perineural Invasion:

Identified

Surgical Margins:

Tumor present at right ureteral margin

Tumor present at left ureteral margin

Non-Neoplastic Mucosa:

Exhibiting ulceration

Exhibiting foreign body reaction

Exhibiting proliferative cystitis (Brunn's nests, cystitis cystica, cystitis glandularis)

[page 3 of 6]
SURGICAL PATHOLOGY REPORT

Female Genital Organs:

The vagina shows no pathologic changes

Perivesical Lymph Nodes:

Not identified

The Pathologic Stage is (AJCC 2002):

pT3 (Invasion of perivesicle soft tissue)

9. Stent, left ureter; removal:

-Stent, gross examination only.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result Spec

CD11

DES

CMA(HHF35)

S100

NEG

IMM

al Stain
7

Comment

CONT
RECUT

Gross Description:

1. The specimen is received fresh, labeled "small bowel implant". It consists of one piece of tan red soft tissue measuring 0.9 x 0.9 x 0.8 cm. The specimen is bisected and submitted entirely for frozen section.

Summary of Sections:

FSC- frozen section control

2.) The specimen is received fresh, labeled "right common iliac lymph nodes" and consists of one pink tan firm lymph node measuring 0.6 x 0.4 x 0.2 cm. The specimen is entirely submitted.

Summary of sections:

LN - lymph nodes

3.) The specimen is received fresh, labeled "right pelvic lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.2 cm to 1.2 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN - lymph nodes

4.) The specimen is received fresh, labeled "presacral lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.1 cm to 0.4 cm in greatest dimension. All identified lymph nodes are submitted.

[page 4 of 6]
SURGICAL PATHOLOGY REPORT

Summary of sections:
LN - lymph nodes

5.) The specimen is received fresh, labeled "lymph node from Marcille" and consists of one possible pink tan firm lymph node measuring 1.2 x 0.5 x 0.3 cm. The specimen is entirely submitted.

Summary of sections:
LN - lymph node

6.) The specimen is received fresh, labeled "left pelvic lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.3 cm to 1.8 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:
LN - lymph nodes
BLN - bisected lymph nodes

7.) The specimen is received fresh, labeled "left common iliac lymph nodes" and consists of one pink tan firm lymph node measuring 0.5 x 0.4 x 0.2 cm. The specimen is entirely submitted.

Summary of sections:
LN - lymph nodes

8. The specimen is received fresh, labeled "bladder, urethra and anterior vaginal wall". It consist of a bladder and anterior vaginal wall with bilatera ureters measuring 13cm from superior to inferior, 10 cm laterally and 4cm from anterior to posterior. The bladder measures 12 x 10 x 4 cm. The portion of vaginal cuff measures 2x 1.5 x 0.6 cm. The distal urethra and the vaginal cuff margin are shaved and submitted. The ureteric stumps measure 0.6 cm in lenght and 0.2 cm in diamter. The specimen is inked green on the right side and blue on the left side and the bladder is opened anteriorly to reveal an infiltrating firm lesion 5.5x 3.5 x 3.0 cm. The lesion is located in the left postero lateral wall and extends to the dome region. The distance from the left and the right ureteric orifices are 0.4 cm and 2.8 cm respectively. On sectioning, the tumor extends to a depth of 3.0cm, and is approaching the perivesical fat grossly. The remaining bladder mucosa shows edematous mucosa. Discrete perivesical lymph nodes are not identified. Tissue is submitted for TPS. Representative sections are submitted.

Summary of sections:
UTHM - distal urethra
RUM - right ureter margin
LUM - left ureter margin
L - lesion
RUO - right ureteric orifice
LUO - left ureteric orifice
LP- left posterior wall
LA - left anterior wall
RP- right posterior wall
RA - right anterior wall
TRI - trigone
DOME - dome
F - perivesical fat
DVM - distal vaginal margin

9). The specimen is received fresh labeled, "Stent from left ureter" and consists of an elongated tubular blue stent measuring 25 x 0.3 x 0.3 cm. The specimen is photographed. Gross only.

[page 5 of 6]
SURGICAL PATHOLOGY REPORT

Summary of Sections:

Part 1: Small intestine, "implants"; biopsy

Block	Sect. Site	PCs
1	FSC	1

Part 2: Lymph nodes, right common iliac; excision

Block	Sect. Site	PCs
1	LN	1

Part 3: Lymph nodes, right pelvic; excision

Block	Sect. Site	PCs
5	LN	5

Part 4: Lymph nodes, presacral; excision

Block	Sect. Site	PCs
1	LN	1

Part 5: Lymph node, Marcille's; excision

Block	Sect. Site	PCs
1	LN	1

Part 6: Lymph nodes, left pelvic; excision

Block	Sect. Site	PCs
2	BLN	2
2	LN	2

Part 7: Lymph nodes, left common iliac; excision

Block	Sect. Site	PCs
1	LN	1

Part 8: Bladder, urethra and anterior vaginal wall; radical cystectomy

Block	Sect. Site	PCs
1	DOMÉ	1
1	DVM	1
1	F	1
6	L	6
1	LA	1
1	LP	1
1	LUM	1
1	LUO	1
1	RA	1
1	RP	1
1	RUM	1
1	RUO	1
1	TRI	1
1	UTHM	1

Part 9: Stent, left ureter; removal

[page 6 of 6]
SURGICAL PATHOLOGY REPORT

Intraoperative Consultation:

1. Frozen section diagnosis: Small bowel implants Spindle cell proliferation
Permanent diagnosis: See final

Source: NCI Genomic Data Commons file 129595cb-d662-49df-b0a0-edf488cf4c8d (TCGA-DK-A2HX.D531397C-85E3-4C46-BB9C-0780CBFE25D6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).